Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XY, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XY-01A (Primary Tumor).

[page 1 of 4]
Sex:F

Pathology Report

Accession Number:
Type: Surgical Pathology
Specimen Type: Soft tissue tumor, extensive resection
Procedure Date:
Ordering Provider:

Report Status: Amend/Addenda

ICD-O.3

Leiomyosarcoma 8890/3
Site retroperitoneum C48.0
path Mesentery C48.1
JW 5/5/14

CASE:

PATIENT: [REDACTED]

***** Added Report *****

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

A. MASS, MESENTERY, WITH ATTACHED SMALL BOWEL X2 AND LEFT COLON, RESECTION:
LEIOMYOSARCOMA, intermediate to high grade, (32 cm), located in the wall of the small intestine, with overlying mucosal ulceration.
Extensive tumor necrosis with bacterial colonization is present.
Tumor perforates the serosal surface.
Mitoses number at least 17 per 10 hpfs.
Separate segment of small intestine (28.0 cm) and colon (25.0 cm) with serosal adhesions to the tumor mass.
All the resection margins of attached intestine are negative for tumor.

B. OMENTUM, RESECTION:
FibroadiPOSE tissue with fat necrosis, abscess formation, marked acute and chronic inflammation; negative for tumor.

C. LEFT KIDNEY, NEPHRECTOMY:
Kidney with three simple cysts (largest 2.0 cm)
Portion of adrenal gland with hyperplastic changes.
No tumor present.
Sections of the kidney will be forwarded to the _____ and the findings will be reported in an addendum.

D. MASS, LEFT ADRENAL GLAND:
Adrenal cortical adenoma, unencapsulated (approximately 5.0 cm, 10.9 g including attached adrenal gland), surrounded by rim of adrenal gland with hyperplastic changes.
Mitoses number <1 per 10 hpfs.
No atypical mitosis or lymphovascular invasion is identified.

NOTE: This portion of the case was reviewed by Dr. _____, who concurs.

E. SPECIMEN LABELLED ?ADDITIONAL MESENTERIC MASS?:
LEIOMYOSARCOMA, intermediate to high grade, 14.0 cm.
Tumor extends to specimen edges.
Necrosis is present.

F. SPECIMEN LABELLED ?STOMA?:
Portion of colon with acute serositis, negative for tumor.
Adenoma, incidental.

CLINICAL DATA:

History: Sarcoma - intra-abd.
Operation: Resection intra-abd mass.
Operative Findings: None given.
Clinical Diagnosis: Intra-abd mass.

TISSUE SUBMITTED:

- A/1. Mesenteric mass, small bowel X2, left colon FS.
- B/2. Omentum.
- C/3. Left kidney.
- D/4. Left adrenal.
- E/5. Additional mesenteric mass.
- F/6. Stoma.

[page 2 of 4]
Pathology Report**GROSS DESCRIPTION:**

The specimen is received fresh in six parts, each labeled with the patient's name and medical record number.

Part A, "#1. Mesenteric mass, small bowel X2, left colon FS", consists of a tan/yellow soft tissue mass (32.0 x 27.8 x 14.8 cm) with two adhered unoriented segments of small bowel (28.0 cm in length x 3.0 cm in diameter, adheres to superficial/anterior aspect of the mass; and 24 cm in length x 4.2 cm in diameter, adheres to posterior aspect of the mass) and an oriented adherent large bowel (25.0 cm in length x 4.5 cm in diameter, adhere to posterior aspect of the mass). Most of the mass are covered by fascia/peritoneum except one area (5.0 x 4.0 cm) with exposed tumor and is labeled as deep per surgeon. Serial section of the mass revealed a large necrotic cavity (17.0 x 14.0 x 8.0 cm) at the center of the mass that is filled with tan/pink/green/yellow necrotic material and is communicating posteriorly with one (the 24 cm long one) segment of small bowel along most of its length (17.0 cm). This necrotic cavity focally erodes through the overlying fascia/peritonea at the central anterior aspect of the mass with tan/green exudate. Representative section of the tumor is submitted for cytogenetics, EM, quick fix. Representative section of normal colon is also submitted for tissue banking.

Micro A1: Quick fix, 2 frags,

Micro A2: Two stapled resection margin (one inked blue and the other inked black) of the segment of small bowel that communicates with the necrotic cavity of the mass, perpendicular section, 2 frags,

Micro A3-A4: Representative section of the necrotic cavity of the mass communicating with the small bowel, 2 frags, 1 frag in each block,

Micro A5: Representative section of the segment of bowel that communicates with the mass, 1 frag,

Micro A6-A8: Representative section of the mass, 3 frags,

Micro A9: The area where the peritoneum covers the cavity of the mass is eroded through, 1 frag,

Micro A10: Two stapled resection margin (both inked blue) and representative section of the second segment of small bowel (28 cm long) that adheres to the mass at the anterior side and close to the peritoneal perforation site, 3 frags,

Micro A11: Adhesion of the second segment of small bowel to the mass, 1 frag,

Micro A12: Tumor in relation to the deep resection margin (inked black), 1 frag,

Micro A13: Representative section of the large bowel in relation to the adhered mass through pericolic adipose tissue, 1 frag,

Micro A14: Proximal and distal stapled resection margin of the large bowel (proximal inked black and distal inked blue), 2 frags,

Micro A15: Representative section of the large bowel, 1 frag,

Part B, "#2. Omentum", consists of two fragments of tan/yellow/pink adipose tissue (8.0 x 6.0 x 1.5, 8.0 x 5.0 x 1.0 cm) with focal tan/white fibrotic area.

Micro B1+B2: Representative section of the fibrotic area of omentum, 4 frags, 2 frags in each block,

Micro B3: Uninvolved omentum, 2 frags,

Part C, "#3. Left kidney", consists of a 426 gram nephrectomy specimen (20.0 x 8.0 x 7.0 cm), including left kidney (12.0 x 6.0 x 5.5 cm), part of the left adrenal gland (2.0 x 1.0 x 0.3 cm) at upper pole and the surrounding perirenal fat (measuring in thickness from 0.2 to 1.5 cm). Extending from the renal pelvis is a short segment of ureter (0.5 cm in length x 0.3 cm in diameter), renal vein (0.5 cm in length x 1.0 cm in diameter), and two renal arteries (0.5 cm in length and 0.3 cm in diameter each). There is no growth lesion identified except three cortical cysts (one 2.0 cm at the upper pole, one 2.0 cm at mid-lateral side and one 0.5 cm at mid-anterior). The renal cortex is tan/brown with a well-defined corticomedullary junction. The pelvis and calices are covered by smooth glistening mucosa. The adrenal gland consists of normal medulla and cortex without focal lesion. The adipose tissue is serially sectioned and no lymph nodes are found.

[page 3 of 4]
Sex:F

Pathology Report

Micro C1: Ureter, renal vein, renal artery resection margin, 4 frags,
Micro C2: Smallest cortical cyst, 1 frag,
Micro C3: Larger cortical cyst at mid lateral of the kidney, 1 frag,
Micro C4: Renal parenchyma in relation to renal pelvis, 1 frag,
Micro C5: Adrenal gland in relation to the renal parenchyma and the other large cortical cyst at the upper pole, 1 frag,

Part D, "#4. Left adrenal", consists of a 10.9 gram adrenal gland (5.0 x 3.0 x 2.0 cm) with attached tan yellow adipose tissue (4.0 x 2.0 x 0.7 cm). The adrenal gland is serially sectioned and revealed a cystic mass filled with necrotic tan/red material (1.7 cm in diameter).

Micro D1-D3: Representative section of adrenal gland including the cystic mass, 3 frags, 1 frag in each block.

Part E, "#5. Additional mesentery mass", consists of a 490 gram tan/pink/yellow mass (14.0 x 10.0 x 8.0 cm) with two other separate smaller fragments (3.5 x 3.0 x 2.5 and 3.0 x 2.0 x 2.0 cm). The mass appears focally hemorrhagic and possibly necrotic.

Micro E1-E5: Representative section of the mass, necrotic/hemorrhagic area in cassettes E4 and E5, 5 frags, 1 frag in each block,

Part F, "#6. Stoma", consists of a segment of bowel (8.0 cm in length x 3.0 cm in diameter) with two stapled resection margins (one inked black and the other inked blue). There is a polyp (0.5 cm) that is 1.0 cm from the blue inked stapled resection margin. The mucosa appears edematous with no other mass or lesion identified.

Micro F1: Blue inked stapled resection margin in relation to the polyp, 2 frags,

Micro F2: Black inked stapled resection margin, 1 frag,

CASE NUMBER:

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by

Electronically signed on

ADDENDUM:

C. LEFT KIDNEY, RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

EXTENSIVE ACUTE TUBULAR INJURY WITH PROMINENT DISTENSION OF THE LUMEN
(SEE NOTE)

MODERATE CHRONIC CHANGES OF THE PARENCHYMA, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (10% OF GLOMERULI)
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (20% OF PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE

NOTE:

The kidney parenchyma shows universal tubular damage with luminal distension and moderate chronic parenchymal changes. The pattern of tubular injury is non-specific and can be associated with obstruction or acute tubular injury, either toxic or ischemic in nature. In this patient it is very likely that

[page 4 of 4]
Sex: F

Pathology Report

distal obstruction is an important contributing cause. The parenchyma also shows moderate chronic changes most likely related to vascular damage

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block C4) were evaluated using H&E, PAS, Jones' methenamine silver, and AFOG (trichrome) stains

The sample consists of cortex and medulla. There are 238 glomeruli present. Twenty-three (23) glomeruli are globally obsolescent (sclerosed), which are located primarily in the subcapsular cortex. Occasional hypoperfused glomeruli are also seen. The remaining glomeruli show mild expansion of the mesangial matrix; otherwise, the glomerular architecture is well-preserved. The peripheral capillary walls appear normal in thickness and texture. No craters are seen. There are widespread signs of tubular injury, characterized by marked distension of the lumen, attenuation of the tubular epithelium, blunting of the brush border, and cytoplasmic vacuolization. Patchy tubular atrophy is seen and is associated with a mild-to-moderate collection of PAS-positive hyaline and granular casts in distal segments. A patchy interstitial lymphoplasmacytic infiltrate is also seen in association with the atrophy. Occasional calcium phosphate deposits are present. Approximately 20% of the sample shows tubular atrophy and interstitial fibrosis, as demonstrated by the trichrome stains (AFOG). Arteries and arterioles show moderate sclerosis of the vessel walls. A vein in the corticomedullary junction exhibits muscular hyperplasia.

Addendum #1 by

Electronically signed on

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file fc63d657-5702-40cd-9fb5-8b684f331174 (TCGA-WK-A8XY.37799A6B-C555-4591-8D83-672ABA931A83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).